Somatic mutation profile of tumor specimen 0DVJOI from CCDI case PBCMNT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,076 days).
Specimen 0DVJOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fff189b-987e-4781-a544-e1a3506209b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe2c6914-836a-4779-b678-503dbaae0aa7

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 769/1623 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CD40 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 651/1337 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361629901, COSV100953861; called by muse, mutect2, varscan2
- NR2C1 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 22/959 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1488600975; called by muse, mutect2
- PDCD11 | c.4798C>T p.R1600W | Missense Mutation (SNP) | VAF 242/700 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs746811823, COSV53294730; called by muse, mutect2, varscan2
- ATP10B | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 34/1028 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DCAF6 | c.323A>C p.D108A | Missense Mutation (SNP) | VAF 352/746 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FAM83B | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 43/1603 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPTBN4 | c.6001T>G p.C2001G | Missense Mutation (SNP) | VAF 28/1016 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- TAF15 | c.299G>T p.G100V (on ENST00000605844 / NM_139215.3; = p.G97V on NM_003487.4) | Missense Mutation (SNP) | VAF 58/503 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- TCHHL1 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 387/942 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C3 | c.2985C>T p.V995= | Silent (SNP) | VAF 28/1094 reads (3%) | catalogued as COSV99835974; called by muse, mutect2
- NECTIN1 | c.327C>A p.I109= | Silent (SNP) | VAF 24/696 reads (3%) | catalogued as COSV99872213; called by muse, mutect2
- FOXP1 | c.1652+18G>A | Intron (SNP) | VAF 273/483 reads (57%) | called by muse, mutect2, varscan2
- OPA3 | c.*8C>T | 3'UTR (SNP) | VAF 19/538 reads (4%) | called by muse, mutect2
- RPL18 | c.297+89C>A | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
